Gene-level copy-number profile of tumor specimen C3L-02647-01 (profiled together with C3L-02647-02, C3L-02647-03, C3L-02647-04) from CPTAC case C3L-02647, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.1 years (25,244 days).
Specimen C3L-02647-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e62042fa-e447-44dc-a33f-a2cb875d5716.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02647-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/73c71077-7c7d-462e-bf22-3a9faff34ff2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 13,481; copy number 2: 39,040; copy number 3: 6,153; copy number 4: 73; copy number 5: 141.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr16:11,555–53,608, 7 genes (within-gene range 0–1): DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K.
- chr16:28,341,437–28,492,098, 10 genes (within-gene range 0–1): AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 141 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:2,135,977–3,680,143, 141 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,625. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
